Somatic mutation profile of tumor specimen TARGET-20-PASWPD-09A (aliquot TARGET-20-PASWPD-09A-02D) from TARGET case TARGET-20-PASWPD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,454 days).
Specimen TARGET-20-PASWPD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b6f25f7-a790-465e-8714-f85df7f2c7c4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASWPD-14A (Bone Marrow Normal), aliquot TARGET-20-PASWPD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd263ba4-b12e-4d38-8e7f-a283a5c61ca3

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1313466, COSV55548621, COSV55708344, COSV56208539; called by muse, mutect2, varscan2
- WT1 | c.1105_1108dup p.A370Vfs*4 | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | catalogued as COSV60065440; called by mutect2, varscan2
